Somatic mutation profile of tumor specimen TCGA-14-1450-01B (aliquot TCGA-14-1450-01B-01D-1845-08) from TCGA case TCGA-14-1450, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.4 years (20,960 days).
Specimen TCGA-14-1450-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16ce59b-0cad-4aba-81f3-a67d2a9cb3ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1450-10B (Blood Derived Normal), aliquot TCGA-14-1450-10B-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d643a472-6934-4272-9bd0-6bd0c3160477

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.272A>C p.H91P | Missense Mutation (SNP) | VAF 128/643 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100947678, COSV64419034, COSV64420066; called by muse, mutect2, varscan2
- ADH1C | c.225A>T p.E75D | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV101565179, COSV101565202, COSV72463662; called by muse, mutect2, varscan2
- AHNAK2 | c.4772T>A p.L1591H | Missense Mutation (SNP) | VAF 139/454 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV60930574; called by muse, mutect2, varscan2
- ANKRD17 | c.4088G>A p.G1363D | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58227784; called by muse, mutect2, varscan2
- ARHGEF6 | c.2061A>T p.Q687H | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV51695967; called by muse, mutect2
- C8A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201034819, COSV63483573; called by muse, mutect2, varscan2
- CACNA1E | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760975849, COSV62380904; called by muse, mutect2, varscan2
- CCDC110 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs376940059; called by muse, mutect2, varscan2
- CYP3A7 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs774768130, COSV60481775; called by muse, mutect2, varscan2
- DDIAS | c.774T>A p.F258L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV61273272; called by muse, mutect2, varscan2
- DYNC1I1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1423892270, COSV61471293; called by muse, mutect2
- ETS1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1045241125, COSV60091363; called by muse, mutect2, varscan2
- GFRA1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1378070060, COSV62606471; called by muse, mutect2
- GLI1 | c.1291G>C p.V431L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV57367392; called by muse, mutect2, varscan2
- GLYATL2 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV54851553; called by muse, mutect2, varscan2
- GSPT2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61215179; called by muse, mutect2, varscan2
- HEATR5B | c.5854G>A p.V1952I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV51859111; called by muse, varscan2
- IL1RN | c.490G>A p.E164K (on ENST00000409930 / NM_173842.3; = p.E146K on NM_000577.5) | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV52082001; called by muse, mutect2, varscan2
- KMT2E | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV57578647, COSV57579742; called by muse, mutect2, varscan2
- LRRC55 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs200453430, COSV73006985; called by muse, mutect2, varscan2
- MKI67 | c.4792C>T p.R1598* | Nonsense Mutation (SNP) | VAF 102/216 reads (47%) | catalogued as rs746363806, COSV64075624; called by muse, mutect2, varscan2
- MLXIPL | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.248); catalogued as COSV57670408; called by muse, mutect2, varscan2
- MMAA | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV55581879; called by muse, mutect2, varscan2
- NMBR | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766550244, COSV57802194; called by muse, mutect2, varscan2
- NRAP | c.2126C>T p.A709V (on ENST00000359988 / NM_001322945.2; = p.A674V on NM_006175.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV63493956; called by muse, mutect2, varscan2
- OR13C5 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66165321; called by muse, mutect2, varscan2
- OR2Y1 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as rs1052153408, COSV57137952; called by muse, mutect2, varscan2
- OR5D18 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61738631; called by muse, mutect2, varscan2
- OSGEP | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs575185404, COSV52833791; called by muse, mutect2, varscan2
- PAPOLA | c.1758C>G p.S586R | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.299); catalogued as COSV53485352; called by muse, mutect2, varscan2
- PNCK | c.932G>A p.R311Q (on ENST00000340888 / NM_001366975.1; = p.R394Q on NM_001039582.3) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.382); catalogued as rs782337569, COSV61745454; called by muse, mutect2
- PRCC | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54857601; called by muse, mutect2, varscan2
- PRKAR2B | c.740T>G p.L247W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55927901; called by muse, mutect2, varscan2
- PROX1 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54783692; called by muse, mutect2, varscan2
- PRPS1L1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 180/654 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.646); catalogued as rs751865681, COSV72649817; called by muse, mutect2, varscan2
- SAPCD2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV68836850; called by muse, mutect2, varscan2
- SH2D4B | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs757811175, COSV57901541; called by muse, mutect2, varscan2
- SLF2 | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.486); catalogued as rs1489052811, COSV53279922; called by muse, mutect2, varscan2
- TENM1 | c.6395G>A p.R2132H | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745618545, COSV64437013; called by muse, mutect2, varscan2
- TRIM8 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56662131, COSV56662592; called by muse, mutect2, varscan2
- TSKS | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.707); catalogued as COSV55879291; called by muse, mutect2, varscan2
- TSPAN16 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57442145, COSV57443551; called by muse, mutect2, varscan2
- TUBA3C | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs778228340, COSV67139976; called by muse, mutect2, varscan2
- ZNF41 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57445197; called by muse, mutect2, varscan2
- TJP1 | c.2792dup p.Y931* | Nonsense Mutation (INS) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- ALPG | c.1365C>T p.D455= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV54968189; called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs199829982; called by muse, mutect2
- CUX2 | c.2466C>T p.R822= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- DAPK3 | c.837G>A p.R279= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV56665127; called by muse, mutect2, varscan2
- DDX10 | c.2424T>C p.D808= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV59439992; called by muse, mutect2, varscan2
- DNAJB5 | c.693C>T p.G231= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs778208193, COSV56627460; called by muse, mutect2, varscan2
- FBN2 | c.3750C>T p.N1250= | Silent (SNP) | VAF 63/194 reads (32%) | catalogued as rs750559514, COSV52544898; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLT1 | c.2307G>A p.A769= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs142392658; called by muse, mutect2, varscan2
- GDF3 | c.132C>T p.F44= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV61713722; called by muse, mutect2, varscan2
- HECTD4 | c.9867G>A p.S3289= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs773525276, COSV66399836; called by muse, mutect2, varscan2
- N4BP3 | c.519C>T p.H173= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs559636054, COSV51067479; called by muse, mutect2, varscan2
- NXPE4 | c.600C>T p.D200= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1213293601, COSV64944403; called by muse, mutect2, varscan2
- PKHD1 | c.1899C>T p.I633= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs751853495, COSV61864959; called by muse, mutect2, varscan2
- PPP1R14C | c.261G>A p.L87= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV63176551; called by muse, mutect2, varscan2
- KNOP1P1 | n.97T>C | RNA (SNP) | VAF 14/389 reads (4%) | called by muse, mutect2
- MIR133B | n.74C>T | RNA (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
